TCGA case TCGA-2H-A9GF — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0500f1a6-a528-43f3-b035-12d3b7c99c0f

Demographics
Sex at birth: male; Country of residence at enrollment: Netherlands; Age at index: 67 years; Vital status: Dead; Days to death: 784 days (2.1 years).

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 67.0 years (24,487 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 8.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Brain, NOS. Age at diagnosis: 67.5 years (24,659 days); Days to diagnosis: 172 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lung, NOS. Age at diagnosis: 67.5 years (24,659 days); Days to diagnosis: 172 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 67.5 years (24,659 days); Days to diagnosis: 172 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 172 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 172 days; Evidence of progression type: Convincing Image Source.
- Day 172 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 172 days; Evidence of progression type: Convincing Image Source.
- Day 172 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 172 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 784 days (2.1 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 95 kg; Height: 183 cm; BMI: 28.4.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2H-A9GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-2H-A9GF-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2H-A9GF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2H-A9GF-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-2H-A9GF-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 70; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: ZH; Cancer procurement city: Rotterdam; History neoadjuvant treatment: No; Tumor status: With tumor; Alcohol history documented: No; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Esoph non CA degree of dysplasia: Negative/no dysplasia; Method initial path diagnosis: Other method, specify:; Lymph node sprd radiograph evidence: Yes; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 784 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 784 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 172 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2H-A9GF-01A-11D-A37B-01): tumor purity 0.68, ploidy 2.84, whole-genome doublings 1.
